Somatic mutation profile of tumor specimen 0DM8W2 from CCDI case PBCADN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DM8W2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b3ae7c3-cd3e-4faf-932c-bae1fff10d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c7cff16-703c-4143-a66d-0234db1c6133

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 7, Intron 5, Frame Shift Ins 2, 3'UTR 2, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 229/499 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH1L1 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747287426, COSV56413750; called by muse, mutect2
- AP5B1 | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 108/711 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.779); catalogued as rs752809282; called by muse, mutect2, varscan2
- ASCL4 | c.153del p.R52Afs*38 | Frame Shift Del (DEL) | VAF 210/495 reads (42%) | catalogued as COSV60817349; called by mutect2, pindel, varscan2
- CLRN2 | c.26G>T p.W9L | Missense Mutation (SNP) | VAF 129/792 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55551231; called by muse, mutect2, varscan2
- FOXK1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 148/799 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as rs1562390149; called by muse, mutect2, varscan2
- GHDC | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 124/579 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761882774, COSV56986853; called by muse, mutect2, varscan2
- IQCB1 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 94/607 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs1456257526; called by muse, mutect2, varscan2
- KCNH8 | c.3227G>T p.G1076V | Missense Mutation (SNP) | VAF 20/784 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.098); catalogued as rs866087313, COSV60473823; called by muse, mutect2
- KMT2C | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 83/602 reads (14%) | catalogued as COSV51418745; called by muse, mutect2, varscan2
- MBNL2 | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 90/637 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs753139788; called by muse, mutect2, varscan2
- NR2C2 | c.1448C>A p.A483E (on ENST00000393102; = p.A502E on NM_003298.5) | Missense Mutation (SNP) | VAF 107/615 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60146578; called by muse, mutect2, varscan2
- OR4X1 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 163/1018 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs759917066; called by muse, mutect2
- TAP1 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 32/810 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs765013700, COSV62753796, COSV62755273; called by muse, mutect2
- ADAMTS14 | c.3262C>T p.L1088F | Missense Mutation (SNP) | VAF 60/978 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CDK11A | c.1574-8C>T | Splice Region (SNP) | VAF 91/409 reads (22%) | called by muse, mutect2, varscan2
- CLRN2 | c.27G>T p.W9C | Missense Mutation (SNP) | VAF 125/793 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- CREB3L3 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 38/916 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- ELAVL4 | c.216A>G p.I72M | Missense Mutation (SNP) | VAF 115/610 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FLNA | c.5235G>T p.Q1745H (on ENST00000369850 / NM_001110556.2; = p.Q1737H on NM_001456.3) | Missense Mutation (SNP) | VAF 39/662 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.212); called by muse, mutect2
- FPR1 | c.753dup p.L252Sfs*19 | Frame Shift Ins (INS) | VAF 118/907 reads (13%) | called by mutect2, pindel, varscan2
- GCNA | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GRIK2 | c.1403G>T p.R468I | Missense Mutation (SNP) | VAF 125/612 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IFIH1 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 51/787 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2
- KLHL2 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 95/494 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LOXHD1 | c.1885T>C p.S629P | Missense Mutation (SNP) | VAF 123/697 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC4C | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 135/1032 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYCBPAP | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 209/1069 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYO5B | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 37/744 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- NFAT5 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 99/716 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by mutect2, varscan2
- NPAS4 | c.1639C>A p.Q547K | Missense Mutation (SNP) | VAF 151/1088 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPIPB11 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OPHN1 | c.200T>A p.F67Y | Missense Mutation (SNP) | VAF 100/676 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR2D2 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 97/690 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POLD3 | c.372C>A p.S124R | Missense Mutation (SNP) | VAF 112/815 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- RANBP9 | c.1298_1299dup p.L434Yfs*12 | Frame Shift Ins (INS) | VAF 50/381 reads (13%) | called by mutect2, pindel, varscan2
- SBF2 | c.1617G>C p.K539N | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- VSTM2A | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 121/829 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XPO4 | c.2923A>C p.T975P | Missense Mutation (SNP) | VAF 60/526 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF799 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 193/1261 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- F8 | c.5889G>T p.L1963= | Silent (SNP) | VAF 91/572 reads (16%) | called by muse, mutect2, varscan2
- GSG1L2 | c.864C>A p.G288= | Silent (SNP) | VAF 89/519 reads (17%) | called by muse, mutect2, varscan2
- IRAK1 | c.480G>T p.L160= | Silent (SNP) | VAF 105/709 reads (15%) | called by muse, mutect2, varscan2
- SEZ6L | c.990C>T p.S330= | Silent (SNP) | VAF 64/424 reads (15%) | catalogued as rs563450794, COSV99962333; called by muse, mutect2, varscan2
- SLC17A1 | c.981C>A p.T327= | Silent (SNP) | VAF 149/878 reads (17%) | called by muse, mutect2, varscan2
- SLC4A2 | c.531G>T p.L177= | Silent (SNP) | VAF 87/748 reads (12%) | called by muse, mutect2, varscan2
- TEKT5 | c.1014C>A p.T338= | Silent (SNP) | VAF 71/438 reads (16%) | called by muse, mutect2, varscan2
- C8orf34 | c.607+66A>C | Intron (SNP) | VAF 29/229 reads (13%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1428-85G>T | Intron (SNP) | VAF 26/119 reads (22%) | called by muse, varscan2
- FTSJ1 | c.-15C>A | 5'UTR (SNP) | VAF 92/498 reads (18%) | called by muse, mutect2, varscan2
- HMGB1 | c.*100G>T | 3'UTR (SNP) | VAF 19/263 reads (7%) | catalogued as rs4002017; called by muse, mutect2
- LILRA5 | c.764-38G>T | Intron (SNP) | VAF 52/221 reads (24%) | catalogued as rs377253147; called by muse, mutect2, varscan2
- MFSD2A | c.1248-53C>T | Intron (SNP) | VAF 61/324 reads (19%) | called by muse, mutect2, varscan2
- PRSS36 | c.110-23G>A | Intron (SNP) | VAF 32/522 reads (6%) | called by muse, mutect2
- TSR1 | c.*14A>T | 3'UTR (SNP) | VAF 81/428 reads (19%) | called by muse, mutect2, varscan2
